Somatic mutation profile of tumor specimen TCGA-AG-3727-01A (aliquot TCGA-AG-3727-01A-01W-0899-10) from TCGA case TCGA-AG-3727, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage III; Age at diagnosis: 78.4 years (28,641 days).
Specimen TCGA-AG-3727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 901f8a7b-90b6-483b-8c3c-03badb7ef321.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3727-10A (Blood Derived Normal), aliquot TCGA-AG-3727-10A-01W-0901-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e580e47d-6244-484c-828c-983b2473fa54

The open-access MAF lists 92 somatic variants for this specimen: 77 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 14, Frame Shift Ins 4, Nonsense Mutation 3, 3'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 84/208 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAP2K4 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 361/452 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62254615; called by muse, mutect2, varscan2
- AFF2 | c.3186G>T p.K1062N | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99666621; called by muse, mutect2
- ANAPC5 | c.1230G>A p.W410* | Nonsense Mutation (SNP) | VAF 82/168 reads (49%) | catalogued as rs1555272538, COSV55845049; called by muse, varscan2
- APC | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 134/156 reads (86%) | catalogued as COSV57323670, COSV57328904, COSV57399512; called by muse, mutect2, varscan2
- APPL1 | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 155/362 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1234269127, COSV99898088; called by muse, mutect2, varscan2
- ARHGEF18 | c.904G>A p.E302K (on ENST00000359920 / NM_001130955.2; = p.E198K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV60473428; called by muse, mutect2, varscan2
- ASTN2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as rs763226599, COSV57804170; called by muse, mutect2
- B4GALT1 | c.389G>T p.C130F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65708769; called by muse, varscan2
- BRDT | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142308966, COSV62863712; called by muse, mutect2, varscan2
- CACNA1B | c.3190G>A p.V1064I | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs1300134377, COSV53141285; called by muse, mutect2, varscan2
- CAND1 | c.2920T>A p.L974M | Missense Mutation (SNP) | VAF 118/248 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101607360; called by muse, mutect2, varscan2
- CARD11 | c.3302G>A p.R1101H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs751651073, COSV67802009; called by muse, mutect2, varscan2
- CATIP | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV99179659; called by muse, mutect2, varscan2
- CSTF2T | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564612037, COSV58656392; called by muse, mutect2, varscan2
- DKK4 | c.317A>C p.E106A | Missense Mutation (SNP) | VAF 154/408 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV55183500; called by muse, mutect2, varscan2
- EBF3 | c.1738G>A p.A580T (on ENST00000355311 / NM_001375392.1; = p.A535T on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as rs567788867, COSV62480805; called by muse, mutect2, varscan2
- FAM24B | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV59027873; called by muse, mutect2, varscan2
- FMNL3 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs770464448, COSV53302231; called by muse, mutect2, varscan2
- FRMPD2 | c.1559A>G p.H520R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564253; called by muse, mutect2
- GAK | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs373690913; called by muse, varscan2
- GRIN2A | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV58061758; called by muse, mutect2, varscan2
- HAP1 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs370934157; called by muse, mutect2, varscan2
- HOXD12 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66832910; called by muse, mutect2, varscan2
- HSPB8 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs1343984954, COSV56139133; called by muse, mutect2, varscan2
- KALRN | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.396); catalogued as rs955692370, COSV99563708; called by muse, mutect2, varscan2
- KIF4B | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775915028, COSV70528329; called by muse, mutect2, varscan2
- KLC4 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs753325985, COSV52438903; called by muse, mutect2, varscan2
- LLGL2 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51341647; called by mutect2, varscan2
- MACF1 | c.11902T>G p.L3968V (on ENST00000372915; = p.L1901V on NM_012090.5) | Missense Mutation (SNP) | VAF 75/171 reads (44%) | catalogued as COSV57140636; called by muse, mutect2
- MAP3K21 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100786191; called by muse, mutect2, varscan2
- MAPKBP1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 105/233 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs201805153, COSV99530284; called by muse, mutect2, varscan2
- MCC | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 209/466 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs578122540, COSV56730424; called by muse, mutect2, varscan2
- MMAA | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 265/594 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs141974563; called by muse, mutect2, varscan2
- MOS | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV61336439; called by muse, mutect2, varscan2
- MYO1E | c.2444A>T p.K815I | Missense Mutation (SNP) | VAF 66/81 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99896779; called by muse, mutect2, varscan2
- NAA40 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.648); catalogued as COSV100624249; called by muse, mutect2, varscan2
- NUP188 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV65360012; called by muse, mutect2
- PABPC3 | c.473T>G p.M158R | Missense Mutation (SNP) | VAF 99/446 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55805794; called by muse, mutect2, varscan2
- PCDHB8 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.751); catalogued as rs782235349, COSV50759260, COSV99175201; called by muse, mutect2, varscan2
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2, varscan2
- PLEKHA5 | c.2640+2T>C p.X880_splice | Splice Site (SNP) | VAF 64/152 reads (42%) | catalogued as COSV100163880; called by muse, mutect2, varscan2
- PPP2R2C | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs904676187, COSV58672024; called by muse, mutect2, varscan2
- PRMT9 | c.422T>G p.F141C | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59361203; called by muse, mutect2, varscan2
- RALBP1 | c.1162A>C p.M388L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.046); catalogued as COSV50038455; called by muse, mutect2, varscan2
- RASGRP1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.317); catalogued as rs764712824, COSV100172358; called by muse, varscan2
- RHOXF2B | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as rs782290026, COSV65054934; called by muse, mutect2, varscan2
- SAP18 | c.332C>A p.S111Y (on ENST00000607003; = p.S130Y on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66822945; called by muse, mutect2, varscan2
- SEMA6B | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370318420; called by muse, mutect2, varscan2
- SIGLEC12 | c.661C>A p.L221I (on ENST00000291707 / NM_053003.4; = p.L103I on NM_033329.2) | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as COSV99389633; called by muse, mutect2, varscan2
- SLC25A43 | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 99/125 reads (79%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV99474800; called by muse, mutect2, varscan2
- SLC37A3 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs781033582, COSV58268071; called by muse, mutect2, varscan2
- SLC6A12 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs901488544, COSV100675232; called by muse, mutect2, varscan2
- SLITRK1 | c.1595A>T p.E532V | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV101000086; called by muse, mutect2, varscan2
- SLITRK1 | c.134del p.K45Rfs*64 | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | catalogued as COSV65676896; called by mutect2, pindel, varscan2
- SLITRK2 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.646); catalogued as COSV100158278; called by muse, mutect2
- SMARCAL1 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1472810771, COSV100620083; called by muse, mutect2, varscan2
- SSTR4 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54796927; called by muse, mutect2, varscan2
- STK31 | c.1739T>A p.I580K | Missense Mutation (SNP) | VAF 372/882 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100670012; called by muse, varscan2
- SVEP1 | c.2459A>G p.E820G | Missense Mutation (SNP) | VAF 145/328 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100239225; called by muse, varscan2
- SYPL2 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1257952857, COSV63995301; called by muse, mutect2, varscan2
- TEC | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 242/667 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs750190240, COSV67405584; called by muse, mutect2, varscan2
- TFR2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779069147, COSV56153870; called by muse, mutect2, varscan2
- THOC1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs1250711792, COSV99863634; called by muse, varscan2
- TMEFF1 | c.689G>T p.R230M | Missense Mutation (SNP) | VAF 103/549 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV58496851; called by muse, mutect2, varscan2
- TMEM132D | c.1884G>T p.Q628H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV101243116; called by muse, mutect2, varscan2
- TRPC5 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 84/97 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749694789, COSV53287947; called by muse, mutect2, varscan2
- VMP1 | c.105G>T p.R35S | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51871732; called by muse, mutect2, varscan2
- VPS54 | c.1889T>G p.L630R | Missense Mutation (SNP) | VAF 25/408 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99708873; called by muse, mutect2
- WDR19 | c.1756T>A p.F586I | Missense Mutation (SNP) | VAF 33/419 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV56469321; called by muse, mutect2
- ZNHIT2 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV54205480; called by muse, varscan2
- AP3D1 | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by mutect2, varscan2
- MAP7 | c.93_94dup p.K32Ifs*51 | Frame Shift Ins (INS) | VAF 158/470 reads (34%) | called by mutect2, pindel, varscan2
- MCF2L2 | c.1257dup p.W420Mfs*12 | Frame Shift Ins (INS) | VAF 109/284 reads (38%) | called by mutect2, pindel, varscan2
- OR6C68 | c.180dup p.L61Sfs*33 | Frame Shift Ins (INS) | VAF 126/774 reads (16%) | called by mutect2, varscan2
- PRIM2 | c.620C>A p.A207D | Missense Mutation (SNP) | VAF 18/604 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTH2R | c.237dup p.K80Efs*13 | Frame Shift Ins (INS) | VAF 151/461 reads (33%) | called by pindel, varscan2
- ABCA10 | c.3954C>T p.L1318= | Silent (SNP) | VAF 84/192 reads (44%) | catalogued as COSV52228814; called by muse, mutect2, varscan2
- COL13A1 | c.1863C>T p.D621= (on ENST00000398978 / NM_001130103.2; = p.D549= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as rs374512468; called by muse, mutect2, varscan2
- ENDOD1 | c.411T>G p.S137= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV53591069; called by muse, mutect2, varscan2
- FCGR2C | c.927C>T p.Y309= | Silent (SNP) | VAF 43/58 reads (74%) | catalogued as COSV63440963; called by muse, mutect2, varscan2
- GBP5 | c.1716C>T p.H572= | Silent (SNP) | VAF 248/580 reads (43%) | catalogued as rs764073054, COSV58594140; called by muse, mutect2, varscan2
- MAN1A2 | c.315A>G p.E105= | Silent (SNP) | VAF 117/276 reads (42%) | catalogued as COSV62981048; called by muse, varscan2
- MSC | c.516C>T p.Y172= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs773546327, COSV57697426; called by muse, mutect2, varscan2
- MYF5 | c.273C>T p.R91= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV57355011; called by muse, mutect2, varscan2
- OPCML | c.630G>A p.A210= | Silent (SNP) | VAF 94/224 reads (42%) | catalogued as rs747460633, COSV59419908; called by muse, mutect2, varscan2
- PCDHB13 | c.78G>A p.A26= | Silent (SNP) | VAF 74/202 reads (37%) | catalogued as COSV53396357, COSV99507733; called by muse, mutect2, varscan2
- PCDHGA5 | c.1605C>T p.S535= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV53909951, COSV54017844; called by muse, mutect2, varscan2
- SSH1 | c.441C>T p.S147= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as rs542173852, COSV58459777; called by muse, mutect2, varscan2
- TBC1D8 | c.1239C>A p.L413= | Silent (SNP) | VAF 69/146 reads (47%) | catalogued as COSV65211224, COSV65216011; called by muse, mutect2, varscan2
- ZNF326 | c.366C>T p.F122= | Silent (SNP) | VAF 92/202 reads (46%) | catalogued as rs142094932; called by muse, mutect2, varscan2
- CPLANE1 | c.*4313A>G | 3'UTR (SNP) | VAF 107/274 reads (39%) | catalogued as COSV99951943; called by muse, varscan2
